Somatic mutation profile of tumor specimen TARGET-10-PASKGG-09A (aliquot TARGET-10-PASKGG-09A-01D) from TARGET case TARGET-10-PASKGG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.6 years (5,682 days).
Specimen TARGET-10-PASKGG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b10bae1-6f3d-45dd-bcb5-12aea15398f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKGG-14A (Bone Marrow Normal), aliquot TARGET-10-PASKGG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7199a532-ad64-48a6-9f5c-d6f847f209e4

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.2326G>T p.G776C | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.423); catalogued as COSV52175260; called by muse, mutect2, varscan2
- COL3A1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1178112512, COSV58582183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201250088, COSV74205737; called by mutect2, varscan2
- OR5B21 | c.893T>A p.L298H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV100835194, COSV64481805; called by muse, mutect2, varscan2
- PCDHB14 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV53388075; called by muse, mutect2, varscan2
- PLXDC2 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.148); catalogued as rs775360529, COSV65902218; called by muse, mutect2, varscan2
- ADAM11 | c.1698C>A p.F566L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.377); called by muse, varscan2
- ATXN2 | c.3735C>T p.H1245= (on ENST00000550104; = p.H1085= on NM_002973.4) | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs1244497847; called by muse, mutect2, varscan2
- LAMC3 | c.2934C>T p.H978= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1238180726, COSV63089656; called by muse, mutect2
- ADAMTSL1 | c.1574+26C>T | Intron (SNP) | VAF 62/73 reads (85%) | called by muse, mutect2, varscan2
- KIF25 | c.317+1520T>C | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- ZNF630 | c.*108C>T | 3'UTR (SNP) | VAF 9/15 reads (60%) | called by mutect2, varscan2
